CPTAC case C3L-03387 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/796c409b-9a37-4a6c-a1e2-518ea3cd9fe7

Demographics
Sex at birth: male; Race: white; Year of birth: 1947; Vital status: Dead; Days to death: 403 days (1.1 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: Russia.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Parietal lobe; Age at diagnosis: 70.7 years (25,839 days); Year of diagnosis: 2018; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 403 days (1.1 years); Progression or recurrence: no; Days to last follow up: 403 days (1.1 years).
   Pathology details: Greatest tumor dimension: 9 cm (a second GDC size field records 5.5 cm).
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 368 days (1.0 years); Disease response: With Tumor; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 403 days (1.1 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 293 days; Karnofsky performance status: 0.

Other clinical attributes
- Weight: 76 kg; Height: 171 cm; BMI: 25.99.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03387-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 243 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03387-21: Section location: Parietal Lobe; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-03387-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
